CPTAC case C3N-03918 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e8502263-1775-4703-b55b-6829f9fe5f12

Demographics
Sex at birth: female; Race: white; Year of birth: 1937; Country of birth: Ukraine.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 80.4 years (29,353 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Residual disease: R0; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Greatest tumor dimension: 4.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 5; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03918-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 120 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03918-21: Section location: Extremities; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-03918-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 100 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03918-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
